Somatic mutation profile of tumor specimen 0DT4J8 from CCDI case PBCJAN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.4 years (4,877 days).
Specimen 0DT4J8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4d75bbe0-605a-4c26-910f-f1c3753eb30a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DT4I7 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/33e3177f-194c-46ef-a0b5-eafd1e550a09

The open-access MAF lists 27 somatic variants for this specimen: 17 protein-altering or splice-affecting, 5 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 5, Intron 4, Nonsense Mutation 2, In Frame Del 1, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1436G>A p.R479Q (on ENST00000281708 / NM_001349798.2; = p.R399Q on NM_018315.5) | Missense Mutation (SNP) | VAF 77/202 reads (38%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs866987936, COSV55890822, COSV55894913, COSV55899054; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CBX7 | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 152/359 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.333); catalogued as rs1333902844, COSV53358684; called by muse, mutect2, varscan2
- CPA2 | c.674G>T p.G225V | Missense Mutation (SNP) | VAF 90/582 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99744160; called by muse, mutect2, varscan2
- FBXL17 | c.672_680del p.G229_G231del | In Frame Del (DEL) | VAF 43/114 reads (38%) | catalogued as rs906102490; called by mutect2, varscan2
- FMR1 | c.1591G>T p.G531* | Nonsense Mutation (SNP) | VAF 229/250 reads (92%) | catalogued as COSV54427846; called by muse, mutect2, varscan2
- ITGB3 | c.1763C>T p.T588M | Missense Mutation (SNP) | VAF 215/401 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.939); catalogued as rs762965827, COSV71385247; called by muse, mutect2, varscan2
- MMP28 | c.1451G>A p.R484H | Missense Mutation (SNP) | VAF 101/553 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as rs1053381994; called by muse, mutect2, varscan2
- OMD | c.1096C>T p.R366* | Nonsense Mutation (SNP) | VAF 137/573 reads (24%) | catalogued as rs760850750; called by muse, mutect2, varscan2
- PKHD1L1 | c.9827_9828del p.F3276Wfs*11 | Frame Shift Del (DEL) | VAF 112/452 reads (25%) | catalogued as rs1351088473; called by mutect2, varscan2
- PSD4 | c.2387C>T p.T796M | Missense Mutation (SNP) | VAF 101/265 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV55525049; called by muse, mutect2, varscan2
- CPNE3 | c.1464G>T p.Q488H | Missense Mutation (SNP) | VAF 47/592 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.216); called by muse, mutect2
- DUSP16 | c.1111T>G p.L371V | Missense Mutation (SNP) | VAF 53/241 reads (22%) | SIFT tolerated (0.68); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- ELOA2 | c.1441G>A p.D481N | Missense Mutation (SNP) | VAF 67/152 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- IL16 | c.479C>T p.A160V | Missense Mutation (SNP) | VAF 150/349 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- PDIA6 | c.56T>A p.V19D | Missense Mutation (SNP) | VAF 143/328 reads (44%) | PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ST8SIA1 | c.915G>T p.Q305H | Missense Mutation (SNP) | VAF 131/316 reads (41%) | SIFT tolerated (0.38); PolyPhen benign (0.409); called by mutect2, varscan2
- ZNF438 | c.1231G>A p.G411S | Missense Mutation (SNP) | VAF 87/518 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CCDC50 | c.90T>C p.A30= | Silent (SNP) | VAF 148/345 reads (43%) | catalogued as rs771813708; ClinVar: likely benign; called by muse, mutect2, varscan2
- CDC42BPB | c.5121G>T p.P1707= | Silent (SNP) | VAF 127/294 reads (43%) | catalogued as COSV100141602; called by muse, mutect2, varscan2
- COL16A1 | c.786G>A p.E262= | Silent (SNP) | VAF 129/275 reads (47%) | called by muse, mutect2, varscan2
- MOCOS | c.819C>T p.G273= | Silent (SNP) | VAF 112/229 reads (49%) | catalogued as rs375133814; called by muse, mutect2, varscan2
- TJP3 | c.216G>A p.A72= | Silent (SNP) | VAF 148/340 reads (44%) | catalogued as rs746317402; called by muse, mutect2, varscan2
- C8orf87 | n.443C>A | RNA (SNP) | VAF 43/174 reads (25%) | called by muse, mutect2, varscan2
- MFSD8 | c.699-79dup | Intron (INS) | VAF 32/78 reads (41%) | catalogued as rs1360948973; called by mutect2, varscan2
- PPP1CB | c.520+56A>G | Intron (SNP) | VAF 13/102 reads (13%) | called by muse, mutect2, varscan2
- SIRT2 | c.947+11G>A | Intron (SNP) | VAF 78/195 reads (40%) | catalogued as rs201193914; called by muse, mutect2, varscan2
- TRPS1 | c.-3+610C>G | Intron (SNP) | VAF 116/366 reads (32%) | called by muse, mutect2, varscan2
